Somatic mutation profile of cancer-model specimen HCM-BROD-0761-C71-85B (Mixed Adherent Suspension, passage 7; aliquot HCM-BROD-0761-C71-85B-01D-A88G-36), derived from the primary tumor of HCMI case HCM-BROD-0761-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.4 years (22,788 days).
Specimen HCM-BROD-0761-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2f496cc-aa2c-4c7a-af79-c19deee81e60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0761-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0761-C71-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6becf9ba-8e53-4078-affc-87bffeb57b07

The open-access MAF lists 99 somatic variants for this specimen: 72 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 25, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 208/648 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANO3 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs1393695079, COSV56784081; called by muse, mutect2, varscan2
- CD247 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 102/464 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs56297636; called by muse, varscan2
- CDCP1 | c.341C>G p.S114W | Missense Mutation (SNP) | VAF 76/379 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.917); catalogued as rs554995721, COSV56105517; called by muse, mutect2, varscan2
- CNTLN | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs774745524, COSV52068787; called by muse, mutect2, varscan2
- COL5A3 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 232/470 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53405418; called by muse, mutect2, varscan2
- COL8A1 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 232/424 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53734856; called by muse, mutect2, varscan2
- DRD5 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 21/527 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1014821510, COSV100431506; called by muse, mutect2
- DTX4 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 204/430 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs376061897; called by muse, mutect2, varscan2
- FKBP1C | c.44C>A p.T15N | Missense Mutation (SNP) | VAF 167/346 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs781733124; called by muse, mutect2, varscan2
- FLOT1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 151/397 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs754804649; called by muse, mutect2, varscan2
- FMN1 | c.3520G>A p.V1174M (on ENST00000616417 / NM_001277313.2; = p.V951M on NM_001103184.4) | Missense Mutation (SNP) | VAF 123/293 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs760909779, COSV100568039; called by muse, mutect2, varscan2
- GFI1B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 303/611 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773869692, COSV59747093; called by muse, mutect2, varscan2
- GPR139 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 178/370 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs760723072, COSV58503347; called by muse, varscan2
- HFM1 | c.2299A>G p.I767V | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); catalogued as rs1450788148; called by muse, mutect2, varscan2
- LILRA6 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 256/802 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.758); catalogued as COSV54433922; called by muse, varscan2
- MKI67 | c.9523G>A p.G3175R | Missense Mutation (SNP) | VAF 281/281 reads (100%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs772736682; called by muse, mutect2, varscan2
- MZF1 | c.1882G>A p.G628S | Missense Mutation (SNP) | VAF 358/763 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1159482628; called by muse, mutect2, varscan2
- NEK11 | c.264C>A p.H88Q | Missense Mutation (SNP) | VAF 87/418 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227738471; called by muse, mutect2, varscan2
- OR4S2 | c.440G>T p.W147L | Missense Mutation (SNP) | VAF 149/331 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV100412701; called by muse, mutect2, varscan2
- OR5D16 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 62/130 reads (48%) | catalogued as rs542655306, COSV65721423; called by muse, mutect2, varscan2
- PAPOLB | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 99/556 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369120981; called by muse, mutect2, varscan2
- PCDH1 | c.3553G>A p.V1185M | Missense Mutation (SNP) | VAF 401/797 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs769661273, COSV54618773; called by muse, mutect2, varscan2
- RGR | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV63895119; called by muse, mutect2
- SLIT2 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 93/239 reads (39%) | catalogued as COSV56564836; called by muse, mutect2, varscan2
- SRCIN1 | c.2648C>T p.T883M (on ENST00000621492; = p.T849M on NM_025248.3) | Missense Mutation (SNP) | VAF 133/293 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs767903662; called by muse, mutect2, varscan2
- TNXB | c.5729C>T p.T1910M (on ENST00000647633; = p.T1663M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/218 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs571091666; called by muse, mutect2, varscan2
- TP53 | c.392A>C p.N131T | Missense Mutation (SNP) | VAF 162/359 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; called by muse, mutect2, varscan2
- TTN | c.65365G>A p.V21789I (on ENST00000591111; = p.V14365I on NM_003319.4) | Missense Mutation (SNP) | VAF 175/416 reads (42%) | PolyPhen probably damaging (0.991); catalogued as rs549709481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.17541G>C p.Q5847H (on ENST00000591111; = p.Q4920H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 193/428 reads (45%) | PolyPhen benign (0); catalogued as COSV60171724; called by muse, mutect2, varscan2
- UNC13C | c.5138G>A p.G1713E | Missense Mutation (SNP) | VAF 122/293 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs901377734, COSV52867250; called by muse, mutect2, varscan2
- USP4 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 155/328 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199948824; called by muse, varscan2
- ZNF648 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 142/757 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1293177797; called by muse, varscan2
- ZNF653 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 289/614 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs1344912460, COSV53402334, COSV99542308; called by muse, mutect2, varscan2
- ABHD12 | c.845C>G p.A282G | Missense Mutation (SNP) | VAF 62/232 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, varscan2
- ADAMTS19 | c.3446G>T p.C1149F | Missense Mutation (SNP) | VAF 136/305 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGB | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 165/438 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- AKNAD1 | c.2270T>A p.M757K | Missense Mutation (SNP) | VAF 149/255 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALG9 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 146/319 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANPEP | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 182/483 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- BTNL9 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 217/506 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC142 | c.1021+1G>A p.X341_splice | Splice Site (SNP) | VAF 136/257 reads (53%) | called by muse, mutect2, varscan2
- DLC1 | c.609A>T p.K203N | Missense Mutation (SNP) | VAF 146/292 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK2 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 91/233 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EBF2 | c.1250G>T p.S417I | Missense Mutation (SNP) | VAF 175/426 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- FREM3 | c.5842G>A p.D1948N | Missense Mutation (SNP) | VAF 121/267 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- GDPD1 | c.759del p.W253Cfs*7 | Frame Shift Del (DEL) | VAF 79/220 reads (36%) | called by mutect2, pindel, varscan2
- HUWE1 | c.11711G>A p.R3904H | Missense Mutation (SNP) | VAF 190/190 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- IGFBP6 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 192/377 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKV1-12 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 138/560 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITPKA | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 96/247 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- KCNB2 | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 207/411 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- KIF1C | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 230/483 reads (48%) | called by muse, mutect2, varscan2
- LRRC49 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LZTR1 | c.1213G>A p.G405S | Missense Mutation (SNP) | VAF 348/348 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- MED27 | c.130A>T p.T44S | Missense Mutation (SNP) | VAF 104/543 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAM2 | c.3025A>G p.K1009E | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO6 | c.3381del p.K1128Rfs*26 (on ENST00000369981; = p.K1118Rfs*26 on NM_004999.4) | Frame Shift Del (DEL) | VAF 108/285 reads (38%) | called by mutect2, pindel, varscan2
- MYORG | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 207/463 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- NAV2 | c.4180C>A p.P1394T (on ENST00000396087 / NM_001244963.2; = p.P1371T on NM_145117.5) | Missense Mutation (SNP) | VAF 246/552 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAPG2 | c.536C>A p.T179K | Missense Mutation (SNP) | VAF 64/402 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NES | c.4267G>A p.E1423K | Missense Mutation (SNP) | VAF 142/351 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- NOS1 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 235/482 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NPR2 | c.2633C>T p.T878I | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2G6 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 166/561 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PASK | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 261/519 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- PIWIL1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 197/469 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRR35 | c.291C>A p.D97E | Missense Mutation (SNP) | VAF 397/812 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRR36 | c.1091G>A p.C364Y | Missense Mutation (SNP) | VAF 251/550 reads (46%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- PSG3 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 198/574 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- USP36 | c.2369A>G p.D790G | Missense Mutation (SNP) | VAF 170/338 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- VWA3B | c.1268A>G p.D423G | Missense Mutation (SNP) | VAF 119/269 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ABCB5 | c.2736G>A p.S912= (on ENST00000404938 / NM_001163941.2; = p.S467= on NM_178559.6) | Silent (SNP) | VAF 114/369 reads (31%) | catalogued as rs760878587, COSV51707168, COSV51708453; called by muse, mutect2, varscan2
- CCDC88B | c.4077G>A p.E1359= | Silent (SNP) | VAF 86/208 reads (41%) | called by muse, mutect2, varscan2
- CHST7 | c.1203C>G p.L401= | Silent (SNP) | VAF 312/312 reads (100%) | catalogued as rs1451361978; called by muse, mutect2, varscan2
- DDI1 | c.247C>A p.R83= | Silent (SNP) | VAF 194/443 reads (44%) | catalogued as rs1167326410, COSV56374584; called by muse, mutect2, varscan2
- DENND5A | c.3000C>T p.F1000= | Silent (SNP) | VAF 155/291 reads (53%) | catalogued as rs778304073, COSV60232221; called by muse, mutect2, varscan2
- EIF2AK1 | c.597G>C p.L199= | Silent (SNP) | VAF 26/297 reads (9%) | called by muse, mutect2
- EPB41L3 | c.240G>A p.Q80= | Silent (SNP) | VAF 177/557 reads (32%) | catalogued as rs974148113; called by muse, mutect2, varscan2
- FA2H | c.843C>T p.I281= | Silent (SNP) | VAF 191/417 reads (46%) | catalogued as rs544646155; called by muse, mutect2, varscan2
- FIGN | c.249G>A p.V83= | Silent (SNP) | VAF 13/407 reads (3%) | called by muse, mutect2
- GNPTG | c.516C>T p.H172= | Silent (SNP) | VAF 160/286 reads (56%) | catalogued as rs377440797; called by muse, mutect2, varscan2
- HACL1 | c.1056T>G p.T352= | Silent (SNP) | VAF 111/246 reads (45%) | called by muse, mutect2, varscan2
- HFM1 | c.3006G>A p.T1002= | Silent (SNP) | VAF 50/152 reads (33%) | catalogued as rs773788286, COSV54023987, COSV99645186; called by muse, mutect2, varscan2
- HOXA6 | c.216C>T p.Y72= | Silent (SNP) | VAF 161/897 reads (18%) | catalogued as rs764406083, COSV56073005; called by muse, mutect2, varscan2
- MUC5B | c.807G>A p.P269= | Silent (SNP) | VAF 308/629 reads (49%) | catalogued as rs755697172; called by muse, mutect2, varscan2
- NOX3 | c.1335T>C p.D445= | Silent (SNP) | VAF 54/299 reads (18%) | catalogued as rs773335268; called by muse, mutect2, varscan2
- PKD1 | c.6567G>A p.V2189= | Silent (SNP) | VAF 322/665 reads (48%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.3069C>T p.N1023= | Silent (SNP) | VAF 78/234 reads (33%) | called by muse, mutect2
- SIM1 | c.1362G>A p.S454= | Silent (SNP) | VAF 286/550 reads (52%) | catalogued as COSV53491165; called by muse, mutect2, varscan2
- SLC1A7 | c.1194C>T p.Y398= | Silent (SNP) | VAF 183/307 reads (60%) | catalogued as rs377738768; called by muse, mutect2, varscan2
- SLMAP | c.1149C>T p.V383= (on ENST00000428312 / NM_001377924.1; = p.V404= on NM_007159.5) | Silent (SNP) | VAF 179/357 reads (50%) | catalogued as rs139832644; called by muse, mutect2, varscan2
- TMEM200A | c.36C>T p.A12= | Silent (SNP) | VAF 175/381 reads (46%) | catalogued as rs368801042; called by muse, mutect2, varscan2
- TPRN | c.1329G>A p.K443= | Silent (SNP) | VAF 212/526 reads (40%) | called by muse, mutect2, varscan2
- UGGT2 | c.1176C>T p.D392= | Silent (SNP) | VAF 66/257 reads (26%) | catalogued as rs145424874; called by muse, mutect2, varscan2
- XCR1 | c.777C>T p.C259= | Silent (SNP) | VAF 229/475 reads (48%) | catalogued as rs573724659, COSV58569890; called by muse, mutect2, varscan2
- ZNF670 | c.231C>T p.G77= | Silent (SNP) | VAF 124/381 reads (33%) | called by muse, mutect2, varscan2
- ISCA2P1 | chr22:26646645 G>A | 5'Flank (SNP) | VAF 271/272 reads (100%) | called by muse, mutect2, varscan2
- LCORL | chr4:17875896 C>G | 3'Flank (SNP) | VAF 14/282 reads (5%) | called by muse, mutect2
